Somatic mutation profile of tumor specimen 0DF095 from CCDI case PBBREK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.8 years (3,566 days).
Specimen 0DF095: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6b1257f-6805-4194-9243-aab619f86197.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF096 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05411e6d-d4a6-4b54-a720-598b017f516b

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 2, RNA 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.4843G>T p.E1615* | Nonsense Mutation (SNP) | VAF 137/931 reads (15%) | catalogued as COSV52228263; called by muse, varscan2
- HLA-DOA | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 98/756 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as rs200140467; called by muse, varscan2
- SZT2 | c.7933C>A p.P2645T (on ENST00000634258 / NM_001365999.1; = p.P2588T on NM_015284.4) | Missense Mutation (SNP) | VAF 122/886 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65170242; called by muse, varscan2
- TMEM86B | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 240/608 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs749232097, COSV58984392; called by muse, varscan2
- ABCD3 | c.1756T>A p.Y586N | Missense Mutation (SNP) | VAF 206/829 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ABCE1 | c.736T>C p.Y246H | Missense Mutation (SNP) | VAF 573/1036 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- AMER2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 188/408 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, varscan2
- ANO8 | c.1516T>C p.W506R | Missense Mutation (SNP) | VAF 201/498 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.076); called by muse, varscan2
- PPFIBP2 | c.1844C>A p.A615E | Missense Mutation (SNP) | VAF 698/966 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CAP2 | c.21G>C p.L7= | Silent (SNP) | VAF 616/794 reads (78%) | called by muse, varscan2
- QRICH2 | c.1515C>T p.V505= | Silent (SNP) | VAF 122/750 reads (16%) | called by muse, varscan2
- TTN | c.71901G>A p.L23967= (on ENST00000591111; = p.L16543= on NM_003319.4) | Silent (SNP) | VAF 135/1016 reads (13%) | called by muse, varscan2
- ZNF570 | c.1365G>A p.S455= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs763278288; called by muse, varscan2
- AP003059.1 | n.13G>A | RNA (SNP) | VAF 66/70 reads (94%) | called by muse, varscan2
- FBXL21P | n.1603G>A | RNA (SNP) | VAF 194/450 reads (43%) | catalogued as rs376323615; called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 14/142 reads (10%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 9/73 reads (12%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/265 reads (10%) | called by muse, varscan2
